Somatic mutation profile of cancer-model specimen HCM-CSHL-0318-C18-85B (3D Organoid, passage 7; aliquot HCM-CSHL-0318-C18-85B-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0318-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Tumor grade: G2.
Specimen HCM-CSHL-0318-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed1bee56-9ab1-4b68-a753-7d9f8cbc63b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0318-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0318-C18-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f93d4ec-f96a-454a-baa3-aafffe84bab1

The open-access MAF lists 130 somatic variants for this specimen: 94 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 32, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 2, Intron 2, 5'Flank 1, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 97/205 reads (47%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 267/597 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC38A8 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 116/387 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs372929441, CM1312211, COSV55307033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOD1 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 214/615 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755737247, COSV66291675; called by muse, mutect2, varscan2
- AGBL4 | c.435C>A p.N145K | Missense Mutation (SNP) | VAF 124/363 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.052); catalogued as rs1338711192; called by muse, mutect2, varscan2
- BCL9 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 209/658 reads (32%) | catalogued as COSV99325076; called by muse, mutect2, varscan2
- BRSK2 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 140/431 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57540340; called by muse, mutect2, varscan2
- CCDC173 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as rs770658227, COSV69573400; called by muse, mutect2, varscan2
- CELF4 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 313/313 reads (100%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs372830155; called by muse, mutect2, varscan2
- CHAT | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 174/272 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs200176236, COSV60319829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 114/352 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs150026024, COSV61833381; called by muse, mutect2, varscan2
- CXCL3 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV56017603; called by muse, mutect2, varscan2
- DLEU7 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 34/576 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1030004185; called by muse, mutect2
- DNAH5 | c.5315C>T p.T1772M | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs754845694; called by muse, mutect2, varscan2
- DSTYK | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 329/505 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs1211244077, COSV100904721; called by muse, mutect2, varscan2
- ETV7 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 218/311 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs377487547; called by muse, mutect2, varscan2
- FAT4 | c.8060G>A p.R2687Q | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs777764521, COSV58675395; called by muse, mutect2, varscan2
- GFRA3 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 411/652 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs573286530; called by muse, mutect2, varscan2
- H2AC1 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 92/293 reads (31%) | catalogued as rs371301750; called by muse, mutect2, varscan2
- ITIH5 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 143/424 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs370892702; called by muse, mutect2, varscan2
- LAMA4 | c.5330C>A p.S1777Y (on ENST00000230538 / NM_001105206.3; = p.S1770Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/281 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57896180; called by muse, mutect2, varscan2
- LZTS3 | c.1777C>T p.R593C (on ENST00000329152; = p.R547C on NM_001282533.2) | Missense Mutation (SNP) | VAF 260/1065 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as rs1369306276, COSV53907522, COSV53908354; called by muse, mutect2, varscan2
- MAML1 | c.2682C>G p.S894R | Missense Mutation (SNP) | VAF 104/1538 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.375); catalogued as rs771710003, COSV52987372; called by muse, mutect2
- MIOS | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 400/401 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs534931594; called by muse, mutect2, varscan2
- MRPL37 | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 290/806 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs950177013; called by muse, mutect2, varscan2
- NAAA | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 102/265 reads (38%) | catalogued as rs764621735; called by muse, mutect2, varscan2
- NBEA | c.6863G>A p.R2288H | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745768265; called by muse, mutect2, varscan2
- NCR3LG1 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 20/608 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.07); catalogued as rs1381398484; called by muse, mutect2
- ORC4 | c.1125T>A p.A375= | Splice Region (SNP) | VAF 38/123 reads (31%) | catalogued as COSV51574430; called by muse, mutect2, varscan2
- OSBPL2 | c.286G>A p.A96T (on ENST00000313733 / NM_144498.4; = p.A84T on NM_014835.4) | Missense Mutation (SNP) | VAF 104/662 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.426); catalogued as rs767354660; called by muse, varscan2
- PCDHGA8 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 183/534 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1406338034; called by muse, mutect2, varscan2
- PFDN4 | c.63A>C p.Q21H | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65063099; called by muse, mutect2, varscan2
- PIK3CD | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 35/525 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs762697236; called by muse, mutect2
- PLEKHG4 | c.2831G>A p.R944H | Missense Mutation (SNP) | VAF 416/616 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373844590; called by muse, mutect2, varscan2
- PNPLA3 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 120/210 reads (57%) | catalogued as rs144830716, COSV53377228; called by muse, mutect2, varscan2
- SIRPA | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 134/578 reads (23%) | catalogued as rs1335057162, COSV100604991; called by muse, varscan2
- SMIM12 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 162/365 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs1406387110; called by muse, mutect2, varscan2
- SMOC2 | c.1267G>C p.D423H (on ENST00000356284 / NM_001166412.2; = p.D434H on NM_022138.3) | Missense Mutation (SNP) | VAF 92/277 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); catalogued as COSV62438731; called by muse, mutect2, varscan2
- STRIP2 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 378/379 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs942385688, COSV50804101; called by muse, mutect2, varscan2
- SYTL5 | c.2112G>C p.W704C | Missense Mutation (SNP) | VAF 209/427 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936852; called by muse, mutect2, varscan2
- TRIM27 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 334/926 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV65873590; called by muse, mutect2, varscan2
- TTN | c.52674G>C p.E17558D (on ENST00000591111; = p.E10134D on NM_003319.4) | Missense Mutation (SNP) | VAF 114/380 reads (30%) | PolyPhen benign (0); catalogued as rs765951728; called by muse, mutect2, varscan2
- TTN | c.11804T>C p.L3935P (on ENST00000591111; = p.L3889P on NM_003319.4) | Missense Mutation (SNP) | VAF 101/418 reads (24%) | catalogued as COSV60087497; called by muse, mutect2, varscan2
- ZFR2 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 220/640 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs552322198, COSV53598425; called by muse, mutect2, varscan2
- ZNF786 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 213/720 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775726975, COSV60275936; called by muse, mutect2, varscan2
- ABCC4 | c.1762A>G p.I588V | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- AHNAK | c.15833T>A p.V5278D | Missense Mutation (SNP) | VAF 22/678 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ARHGAP32 | c.3493A>G p.R1165G (on ENST00000310343 / NM_001378025.1; = p.R816G on NM_014715.4) | Missense Mutation (SNP) | VAF 117/431 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL9 | c.704del p.P235Hfs*47 | Frame Shift Del (DEL) | VAF 432/818 reads (53%) | called by mutect2, pindel, varscan2
- BTBD18 | c.1281A>T p.Q427H | Missense Mutation (SNP) | VAF 213/575 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CACNA1B | c.4850G>A p.G1617D | Missense Mutation (SNP) | VAF 102/311 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP410 | c.590dup p.Q198Pfs*112 | Frame Shift Ins (INS) | VAF 225/761 reads (30%) | called by mutect2, pindel, varscan2
- CHST10 | c.672_673insC p.Y225Lfs*14 | Frame Shift Ins (INS) | VAF 135/515 reads (26%) | called by mutect2, pindel, varscan2
- CKAP2 | c.1832G>A p.G611E (on ENST00000378037 / NM_001098525.2; = p.G610E on NM_018204.5) | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CNTNAP4 | c.2747T>C p.L916P | Missense Mutation (SNP) | VAF 110/372 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COQ6 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- CPA6 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 109/350 reads (31%) | called by muse, mutect2, varscan2
- CYP7B1 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 139/425 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDI1 | c.739A>G p.N247D | Missense Mutation (SNP) | VAF 116/544 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DHRS9 | c.865del p.I289Ffs*19 | Frame Shift Del (DEL) | VAF 287/565 reads (51%) | called by mutect2, pindel, varscan2
- DNAH5 | c.11983A>G p.R3995G | Missense Mutation (SNP) | VAF 70/325 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- FBLN7 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 238/741 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXJ3 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 524/828 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, varscan2
- FOXJ3 | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 564/868 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, varscan2
- GAS7 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 192/791 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- H4C3 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 29/716 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.83); called by muse, mutect2
- ICE2 | c.408+1G>T p.X136_splice | Splice Site (SNP) | VAF 98/185 reads (53%) | called by muse, mutect2, varscan2
- KIAA0408 | c.1311G>T p.K437N | Missense Mutation (SNP) | VAF 194/288 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- MALRD1 | c.4873C>A p.Q1625K | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- MGAT4C | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.37669T>A p.Y12557N | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- MYO9B | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 185/646 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NBAS | c.6779T>G p.L2260R | Missense Mutation (SNP) | VAF 133/437 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- NCAM2 | c.1752A>C p.E584D | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NCOA1 | c.1979G>A p.C660Y | Missense Mutation (SNP) | VAF 157/501 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR2A12 | c.92T>G p.L31W | Missense Mutation (SNP) | VAF 141/425 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- PCDHB10 | c.349T>C p.Y117H | Missense Mutation (SNP) | VAF 209/337 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PITPNM2 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 162/259 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- SETD4 | c.85_88del p.H29Sfs*5 | Frame Shift Del (DEL) | VAF 57/257 reads (22%) | called by mutect2, pindel, varscan2
- SHANK2 | c.4849_4854del p.S1617_G1618del | In Frame Del (DEL) | VAF 160/501 reads (32%) | called by mutect2, pindel, varscan2
- SLCO4A1 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 193/1234 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SNTG1 | c.1396-1G>A p.X466_splice | Splice Site (SNP) | VAF 89/216 reads (41%) | called by muse, mutect2, varscan2
- SORCS1 | c.2546G>A p.S849N | Missense Mutation (SNP) | VAF 283/466 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAG6 | c.1198-1G>C p.X400_splice | Splice Site (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- SPART | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SYNE2 | c.14651T>G p.I4884R | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- TAF6 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 28/451 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- TMEM200C | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 186/323 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM248 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TOGARAM1 | c.2195G>A p.C732Y | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCAN | c.9119C>G p.S3040C | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ZFHX2 | c.6136G>T p.A2046S | Missense Mutation (SNP) | VAF 247/450 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 170/490 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); called by muse, varscan2
- ZNF354A | c.1172T>A p.F391Y | Missense Mutation (SNP) | VAF 51/611 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ABCA5 | c.3153T>G p.A1051= | Silent (SNP) | VAF 45/167 reads (27%) | called by muse, mutect2, varscan2
- ADGRL2 | c.2886C>T p.A962= (on ENST00000370717 / NM_001366005.1; = p.A949= on NM_012302.4) | Silent (SNP) | VAF 147/252 reads (58%) | called by muse, mutect2, varscan2
- AMH | c.1147C>T p.L383= | Silent (SNP) | VAF 279/911 reads (31%) | catalogued as rs1285543182; called by muse, mutect2, varscan2
- ARMC8 | c.588A>G p.L196= (on ENST00000469044 / NM_001363941.2; = p.L182= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/283 reads (18%) | catalogued as rs762035295; called by muse, mutect2, varscan2
- AUH | c.177G>T p.G59= | Silent (SNP) | VAF 289/853 reads (34%) | called by muse, mutect2, varscan2
- CD163 | c.2403C>T p.H801= | Silent (SNP) | VAF 304/633 reads (48%) | catalogued as rs977803294, COSV63131083, COSV63135337; called by muse, mutect2, varscan2
- CDC42BPA | c.1149G>A p.T383= | Silent (SNP) | VAF 63/274 reads (23%) | catalogued as rs1326261211, COSV62019703; called by muse, mutect2, varscan2
- DOCK4 | c.2046C>G p.L682= | Silent (SNP) | VAF 54/211 reads (26%) | called by muse, mutect2, varscan2
- ELFN1 | c.1776C>T p.S592= | Silent (SNP) | VAF 868/868 reads (100%) | called by muse, mutect2, varscan2
- FBXO40 | c.1383C>T p.S461= | Silent (SNP) | VAF 349/713 reads (49%) | catalogued as rs1450839089, COSV100573263, COSV57527397; called by muse, mutect2, varscan2
- FREM2 | c.4026T>C p.I1342= | Silent (SNP) | VAF 111/366 reads (30%) | called by muse, mutect2, varscan2
- GPR139 | c.81C>T p.F27= | Silent (SNP) | VAF 400/605 reads (66%) | catalogued as COSV58501474; called by muse, mutect2, varscan2
- HERC2 | c.4635G>A p.R1545= | Silent (SNP) | VAF 42/250 reads (17%) | called by muse, mutect2, varscan2
- HGF | c.1557C>T p.C519= | Silent (SNP) | VAF 58/277 reads (21%) | catalogued as rs1258858592, COSV55944770; called by muse, mutect2, varscan2
- HHLA2 | c.1020A>C p.T340= | Silent (SNP) | VAF 26/526 reads (5%) | called by muse, mutect2
- KAT5 | c.807C>T p.Y269= | Silent (SNP) | VAF 125/451 reads (28%) | catalogued as rs111345240; called by muse, mutect2, varscan2
- LTBP3 | c.756C>T p.S252= | Silent (SNP) | VAF 266/890 reads (30%) | called by muse, mutect2, varscan2
- MUC5B | c.5688G>A p.T1896= | Silent (SNP) | VAF 244/786 reads (31%) | catalogued as rs765784256, COSV71591920; called by muse, mutect2, varscan2
- NLGN1 | c.1357A>C p.R453= | Silent (SNP) | VAF 51/516 reads (10%) | catalogued as COSV64337411; called by muse, mutect2, varscan2
- NPBWR1 | c.132C>T p.Y44= | Silent (SNP) | VAF 244/751 reads (32%) | catalogued as COSV58697672; called by muse, mutect2, varscan2
- OTOP2 | c.1650C>T p.H550= | Silent (SNP) | VAF 142/511 reads (28%) | called by muse, mutect2, varscan2
- PCDH10 | c.2067C>T p.G689= | Silent (SNP) | VAF 226/518 reads (44%) | catalogued as rs773534266, COSV52088469; called by muse, mutect2, varscan2
- PCDH17 | c.1047G>A p.P349= | Silent (SNP) | VAF 453/741 reads (61%) | catalogued as COSV64978288; called by muse, mutect2, varscan2
- PCDH18 | c.2616C>T p.D872= | Silent (SNP) | VAF 312/312 reads (100%) | called by muse, mutect2, varscan2
- PROX1 | c.1554T>G p.T518= | Silent (SNP) | VAF 173/603 reads (29%) | called by muse, mutect2, varscan2
- RNF40 | c.2316C>T p.N772= | Silent (SNP) | VAF 127/635 reads (20%) | catalogued as rs764192018, COSV61214597; called by muse, mutect2, varscan2
- SLC25A13 | c.52A>C p.R18= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- SLC45A1 | c.102C>T p.S34= | Silent (SNP) | VAF 239/456 reads (52%) | catalogued as rs758063377; called by muse, mutect2, varscan2
- TRAF2 | c.1347C>T p.P449= | Silent (SNP) | VAF 158/541 reads (29%) | catalogued as rs142950766; called by muse, mutect2, varscan2
- TRIM64C | c.180G>A p.E60= | Silent (SNP) | VAF 191/603 reads (32%) | called by muse, mutect2, varscan2
- TTC30B | c.1365C>T p.N455= | Silent (SNP) | VAF 123/807 reads (15%) | catalogued as rs752622280, COSV68809743, COSV68809867; called by muse, mutect2, varscan2
- VWA5B2 | c.1638C>T p.I546= | Silent (SNP) | VAF 410/933 reads (44%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130916648 C>T | 5'Flank (SNP) | VAF 131/410 reads (32%) | catalogued as COSV58131157; called by muse, mutect2, varscan2
- OR7E19P | n.237G>A | RNA (SNP) | VAF 33/426 reads (8%) | catalogued as rs1053462806; called by muse, mutect2
- OSBPL6 | c.1621+24G>T | Intron (SNP) | VAF 132/410 reads (32%) | called by muse, mutect2, varscan2
- RIMBP2 | c.102+8218A>G | Intron (SNP) | VAF 141/419 reads (34%) | called by muse, mutect2, varscan2
